Somatic mutation profile of tumor specimen C3N-04683-02 (aliquot CPT0293480006) from CPTAC case C3N-04683, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 60.4 years (22,056 days).
Specimen C3N-04683-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Frontal Lobe; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b4913d2c-c2f5-4396-b229-a74c3b3ee507.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-04683-31 (Blood Derived Normal), aliquot CPT0293500002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3715d679-8689-4854-9d5a-a5f6c5672513

The open-access MAF lists 40 somatic variants for this specimen: 26 protein-altering or splice-affecting, 10 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 10, Intron 4, Nonsense Mutation 3, Frame Shift Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 54/216 reads (25%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- NOTCH1 | c.928G>A p.G310R | Missense Mutation (SNP) | VAF 27/407 reads (7%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV53032869; called by muse, mutect2
- ABCC6 | c.1264G>A p.E422K | Missense Mutation (SNP) | VAF 46/309 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.627); catalogued as rs770532500, CM091244, COSV52745281; called by muse, mutect2, varscan2
- AOC3 | c.1382T>G p.V461G | Missense Mutation (SNP) | VAF 31/168 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs771735567; called by muse, mutect2, varscan2
- H1-8 | c.161C>T p.P54L | Missense Mutation (SNP) | VAF 21/157 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.793); catalogued as rs370679132, COSV60973605, COSV60974517; called by muse, mutect2, varscan2
- IKZF1 | c.95C>T p.P32L | Missense Mutation (SNP) | VAF 37/176 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs775793261, COSV58789579; called by muse, mutect2, varscan2
- TOE1 | c.1372C>T p.Q458* | Nonsense Mutation (SNP) | VAF 16/324 reads (5%) | catalogued as rs775296069; called by muse, mutect2
- TPM3 | c.235G>T p.A79S | Missense Mutation (SNP) | VAF 29/466 reads (6%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.86); catalogued as COSV55135572; called by muse, mutect2
- VCAN | c.6244G>T p.G2082C | Missense Mutation (SNP) | VAF 80/274 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.417); catalogued as COSV99424215; called by muse, mutect2, varscan2
- ANKMY1 | c.619G>A p.E207K | Missense Mutation (SNP) | VAF 54/351 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.747); called by muse, mutect2, varscan2
- B3GNT2 | c.437T>C p.L146P | Missense Mutation (SNP) | VAF 22/377 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- C2orf78 | c.835A>T p.T279S | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.16); called by muse, mutect2
- CLEC4M | c.187G>A p.G63R | Missense Mutation (SNP) | VAF 15/244 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.33); called by muse, mutect2
- CRYBG3 | c.2003A>T p.K668M | Missense Mutation (SNP) | VAF 38/145 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- ELF1 | c.705A>T p.K235N | Missense Mutation (SNP) | VAF 6/118 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- FAM240C | c.190G>T p.E64* | Nonsense Mutation (SNP) | VAF 13/119 reads (11%) | called by muse, mutect2, varscan2
- FLG | c.131T>C p.I44T | Missense Mutation (SNP) | VAF 42/297 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- GRN | c.220A>G p.I74V | Missense Mutation (SNP) | VAF 15/445 reads (3%) | SIFT tolerated (0.37); PolyPhen benign (0.003); called by muse, mutect2
- RALGAPA1 | c.3195G>A p.W1065* | Nonsense Mutation (SNP) | VAF 28/167 reads (17%) | called by muse, mutect2, varscan2
- SLC36A3 | c.1210_1220del p.A405Hfs*14 | Frame Shift Del (DEL) | VAF 38/290 reads (13%) | called by mutect2, pindel
- SMC1A | c.1288G>A p.E430K | Missense Mutation (SNP) | VAF 14/231 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); called by muse, mutect2
- UBE2Q2 | c.157C>G p.L53V | Missense Mutation (SNP) | VAF 52/187 reads (28%) | SIFT tolerated (0.49); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- VCAN | c.6245G>T p.G2082V | Missense Mutation (SNP) | VAF 81/276 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- WEE1 | c.1051G>A p.A351T | Missense Mutation (SNP) | VAF 16/160 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- ZNF250 | c.427A>G p.T143A | Missense Mutation (SNP) | VAF 7/180 reads (4%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2
- ZNF652 | c.729_730del p.E243Dfs*5 | Frame Shift Del (DEL) | VAF 136/484 reads (28%) | called by pindel, varscan2
- ACAN | c.7167G>A p.Q2389= (on ENST00000560601 / NM_001369268.1; = p.Q2313= on NM_001135.3) | Silent (SNP) | VAF 43/169 reads (25%) | catalogued as rs1286025925, COSV61355563; called by muse, mutect2, varscan2
- COL1A1 | c.2256T>A p.G752= | Silent (SNP) | VAF 18/377 reads (5%) | called by muse, mutect2
- KRT72 | c.1320C>T p.G440= | Silent (SNP) | VAF 19/242 reads (8%) | catalogued as rs140936315; called by muse, mutect2
- PLAAT4 | c.96C>T p.Y32= | Silent (SNP) | VAF 43/259 reads (17%) | catalogued as rs777708850, COSV55372606; called by muse, mutect2, varscan2
- SLC22A13 | c.777G>A p.A259= | Silent (SNP) | VAF 32/171 reads (19%) | catalogued as rs771713150, COSV100314490; called by muse, mutect2, varscan2
- SNRPN | c.90C>T p.T30= | Silent (SNP) | VAF 39/145 reads (27%) | catalogued as COSV57596293; called by muse, mutect2, varscan2
- TCF3 | c.741G>A p.L247= | Silent (SNP) | VAF 23/219 reads (11%) | called by muse, mutect2, varscan2
- TMEM131L | c.732A>G p.Q244= | Silent (SNP) | VAF 9/113 reads (8%) | catalogued as COSV53643577; called by muse, mutect2
- VKORC1L1 | c.507G>T p.R169= | Silent (SNP) | VAF 66/266 reads (25%) | called by muse, varscan2
- WBP1L | c.657G>A p.R219= | Silent (SNP) | VAF 14/67 reads (21%) | called by muse, mutect2
- AC244517.10 | c.36-10579G>A | Intron (SNP) | VAF 25/173 reads (14%) | called by muse, mutect2, varscan2
- D2HGDH | c.1141-478C>T | Intron (SNP) | VAF 6/114 reads (5%) | called by muse, mutect2
- RNF212 | c.172-2907G>A | Intron (SNP) | VAF 64/408 reads (16%) | catalogued as rs1463694462; called by muse, mutect2, varscan2
- SHLD2 | c.1964-4181_1964-4176del | Intron (DEL) | VAF 29/249 reads (12%) | called by mutect2, pindel, varscan2
